Somatic mutation profile of tumor specimen C3L-05286-03 (aliquot CPT0341100007) from CPTAC case C3L-05286, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 50.2 years (18,323 days).
Specimen C3L-05286-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ac9119e-85de-44e0-a148-79cad1db4365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05286-31 (Blood Derived Normal), aliquot CPT0341180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6380856c-5adf-43c5-81cd-6a2b07d254e5

The open-access MAF lists 84 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 18, Nonsense Mutation 5, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AGBL4 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 79/113 reads (70%) | catalogued as rs1362473143; called by muse, mutect2, varscan2
- ANK3 | c.6391G>A p.E2131K | Missense Mutation (SNP) | VAF 120/187 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV55053323, COSV55058299; called by muse, mutect2, varscan2
- ANK3 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs767300650; called by muse, mutect2, varscan2
- AP4E1 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as rs778403145, COSV55917212; called by muse, mutect2, varscan2
- ARHGAP44 | c.1808G>A p.G603E | Missense Mutation (SNP) | VAF 243/315 reads (77%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV52394421; called by muse, mutect2, varscan2
- ARHGEF16 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 108/163 reads (66%) | catalogued as rs759352437, COSV65683271; called by muse, mutect2, varscan2
- ARL14EPL | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199853691; called by muse, mutect2, varscan2
- ASB6 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 27/438 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs755041021, COSV52964804; called by muse, mutect2
- AURKB | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 254/314 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772022668, COSV60245398; called by muse, mutect2, varscan2
- CES5A | c.1427G>A p.G476E (on ENST00000290567 / NM_001143685.2; = p.G426E on NM_145024.3) | Missense Mutation (SNP) | VAF 94/147 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV51869152; called by muse, mutect2, varscan2
- F13A1 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 128/581 reads (22%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs140712764; called by muse, mutect2, varscan2
- FAM135B | c.3607C>T p.Q1203* | Nonsense Mutation (SNP) | VAF 98/201 reads (49%) | catalogued as rs868642490; called by muse, mutect2, varscan2
- FAM83B | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 138/588 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs149060290; called by muse, mutect2, varscan2
- FZD2 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59529422; called by muse, mutect2, varscan2
- HDGFL1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 501/774 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57752013; called by muse, mutect2, varscan2
- HRH3 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 152/532 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1204125626, COSV58047775; called by muse, mutect2, varscan2
- IGHG2 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 80/333 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs778964699; called by muse, mutect2, varscan2
- KHSRP | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs765261230, COSV101231160; called by muse, varscan2
- LIPI | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV60708652; called by muse, varscan2
- MAST4 | c.1124T>C p.V375A (on ENST00000403625 / NM_001164664.2; = p.V186A on NM_015183.3) | Missense Mutation (SNP) | VAF 104/140 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs748108146; called by muse, mutect2, varscan2
- MTNR1B | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 72/423 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); catalogued as rs1347056510, COSV57065276, COSV57065382; called by muse, mutect2, varscan2
- MYB | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.251); catalogued as rs1310577408; called by muse, mutect2, varscan2
- PLG | c.1987C>T p.R663* | Nonsense Mutation (SNP) | VAF 61/180 reads (34%) | catalogued as rs752522150, CM154959, COSV57513850; called by muse, mutect2, varscan2
- PPARD | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 53/425 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759592721, COSV61099267; called by muse, mutect2, varscan2
- RBM26 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV57400745; called by muse, mutect2
- RNF31 | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as rs1310867659, COSV53761119; called by muse, mutect2, varscan2
- SLITRK6 | c.845C>T p.S282L | Missense Mutation (SNP) | VAF 62/260 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.863); catalogued as rs750992179, COSV68391906; called by muse, mutect2, varscan2
- THEG | c.567G>A p.A189= | Splice Region (SNP) | VAF 40/217 reads (18%) | catalogued as rs186056823, COSV61075153; called by muse, mutect2, varscan2
- TMC2 | c.1855G>A p.D619N | Missense Mutation (SNP) | VAF 123/253 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778650713, COSV62650632; called by muse, mutect2, varscan2
- AGBL1 | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ARID1A | c.4265C>T p.S1422F | Missense Mutation (SNP) | VAF 152/239 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ARID5A | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 191/370 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- BRINP2 | c.1935C>G p.Y645* | Nonsense Mutation (SNP) | VAF 158/248 reads (64%) | called by muse, mutect2, varscan2
- CCDC141 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CCDC51 | c.278_307del p.N93_V102del | In Frame Del (DEL) | VAF 44/310 reads (14%) | called by mutect2, pindel, varscan2
- CD68 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 319/398 reads (80%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CDH12 | c.406dup p.T136Nfs*8 | Frame Shift Ins (INS) | VAF 74/665 reads (11%) | called by mutect2, pindel, varscan2
- CFAP92 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CNGB3 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERAP2 | c.2213G>A p.S738N | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FIZ1 | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by mutect2, varscan2
- IGHV4-28 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 65/402 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.709); called by muse, varscan2
- MCM7 | c.1203C>A p.S401R | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MEP1A | c.83C>A p.P28H | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MLLT10 | c.3070C>T p.L1024F | Missense Mutation (SNP) | VAF 169/234 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MPL | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 142/201 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFRKB | c.71G>T p.R24L (on ENST00000446488 / NM_001143835.2; = p.R37L on NM_006165.3) | Missense Mutation (SNP) | VAF 148/385 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR10H1 | c.370G>C p.V124L | Missense Mutation (SNP) | VAF 93/556 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PHRF1 | c.1990G>A p.G664R (on ENST00000264555 / NM_001286581.2; = p.G663R on NM_020901.4) | Missense Mutation (SNP) | VAF 102/504 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PLA2G4D | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 107/169 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PMIS2 | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 68/375 reads (18%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PNPLA1 | c.1118C>T p.S373L (on ENST00000394571 / NM_001374623.1; = p.S278L on NM_173676.2) | Missense Mutation (SNP) | VAF 171/649 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SIGLEC12 | c.1549G>A p.G517R (on ENST00000291707 / NM_053003.4; = p.G399R on NM_033329.2) | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC26A8 | c.2800C>T p.P934S | Missense Mutation (SNP) | VAF 339/554 reads (61%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPTBN4 | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 95/446 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SRSF6 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 176/331 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAAR6 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 143/226 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- TDRD9 | c.3542C>T p.S1181F | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- THYN1 | c.255del p.K85Nfs*21 | Frame Shift Del (DEL) | VAF 63/328 reads (19%) | called by mutect2, pindel, varscan2
- UGT2B28 | c.1565A>G p.K522R | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF677 | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF705A | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ZSCAN5A | c.1074T>G p.C358W | Missense Mutation (SNP) | VAF 85/365 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C5AR1 | c.249C>T p.F83= | Silent (SNP) | VAF 174/430 reads (40%) | called by muse, mutect2, varscan2
- CCDC158 | c.1272G>A p.R424= | Silent (SNP) | VAF 222/307 reads (72%) | catalogued as COSV101187421; called by muse, mutect2, varscan2
- DCDC2 | c.867G>A p.T289= | Silent (SNP) | VAF 118/449 reads (26%) | catalogued as rs752366929, COSV65830620; called by muse, mutect2, varscan2
- FAT3 | c.3786G>A p.K1262= | Silent (SNP) | VAF 58/332 reads (17%) | catalogued as rs1169674768; called by muse, mutect2, varscan2
- GLI3 | c.3114C>T p.S1038= | Silent (SNP) | VAF 296/569 reads (52%) | catalogued as rs763438834; called by muse, mutect2
- HSD11B1 | c.234C>T p.C78= | Silent (SNP) | VAF 134/200 reads (67%) | catalogued as rs368758549; called by muse, mutect2, varscan2
- IGHV3-49 | c.192G>A p.L64= | Silent (SNP) | VAF 77/194 reads (40%) | called by muse, mutect2, varscan2
- IGKV3-11 | c.198C>A p.L66= | Silent (SNP) | VAF 98/376 reads (26%) | catalogued as rs760335738; called by muse, mutect2, varscan2
- IL36G | c.333C>T p.P111= | Silent (SNP) | VAF 64/230 reads (28%) | catalogued as rs747785140, COSV52077677, COSV52077804; called by muse, mutect2, varscan2
- KRTAP1-5 | c.273C>T p.C91= | Silent (SNP) | VAF 347/466 reads (74%) | catalogued as rs375605370; called by muse, varscan2
- OR2M4 | c.733C>T p.L245= | Silent (SNP) | VAF 84/322 reads (26%) | catalogued as rs897547718, COSV60709200; called by muse, mutect2, varscan2
- OR51B6 | c.579C>T p.N193= | Silent (SNP) | VAF 154/414 reads (37%) | catalogued as COSV66512658; called by muse, mutect2, varscan2
- PAN3 | c.1851T>C p.I617= | Silent (SNP) | VAF 107/270 reads (40%) | called by muse, mutect2, varscan2
- PRKCD | c.1545C>T p.I515= | Silent (SNP) | VAF 87/233 reads (37%) | catalogued as rs782440941, COSV57849737; called by muse, mutect2, varscan2
- SECISBP2 | c.1233C>T p.N411= | Silent (SNP) | VAF 88/203 reads (43%) | catalogued as rs1396430870; called by muse, mutect2, varscan2
- SGCA | c.1122C>T p.R374= | Silent (SNP) | VAF 230/291 reads (79%) | called by muse, mutect2, varscan2
- ZAN | c.7920C>T p.C2640= | Silent (SNP) | VAF 143/408 reads (35%) | catalogued as rs754209557; called by muse, mutect2, varscan2
- ZC3H3 | c.1341C>T p.I447= | Silent (SNP) | VAF 81/336 reads (24%) | catalogued as COSV52787114; called by muse, mutect2
- XIST | n.7806C>T | RNA (SNP) | VAF 71/100 reads (71%) | called by muse, mutect2, varscan2
